Gene-level copy-number profile of tumor specimen TCGA-25-1633-01A from TCGA case TCGA-25-1633, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 64.1 years (23,407 days).
Specimen TCGA-25-1633-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.3ea2b821-8f7a-4430-9b27-16bdc5f0b4d4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-1633-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9dc53ce8-a42f-4ef7-85dc-8b0428a77511

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 129; copy number 1: 4,929; copy number 2: 24,601; copy number 3: 24,406; copy number 4: 4,433; copy number 5: 192; copy number 6: 427; copy number 7: 185; copy number 8: 267; copy number 9: 193; copy number 12: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-25-1633-01): tumor purity 0.63, ploidy 2.59, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 129 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:13,644,775–22,098,518, 129 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 696 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,708,931–43,456,995, 165 genes, copy number 9–12 (broad region; genes not listed).
- chr1:47,067,231–47,314,147, 10 genes, copy number 7 (within-gene range 3–7): CYP4Z1, TUBAP9, CYP4A22-AS1, CYP4A22, MTND1P34, LINC00853, PDZK1IP1, TAL1, AL135960.1, STIL.
- chr4:56,794,348–60,038,586, 39 genes, copy number 7: RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, AC104790.1, SRIP1, AC096725.1, LINC02494, AC019133.1, AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P, AC092596.1, AC097655.1.
- chr18:20,946,906–45,788,670, 323 genes, copy number 7–8 (broad region; genes not listed).
- chr19:20,416,514–22,368,952, 80 genes, copy number 8 (broad region; genes not listed).
- chr20:56,785,981–59,948,680, 79 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,431. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
